CCDI case PBCMNY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/4465013b-39fe-4ae0-bced-02b754576496

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 16.7 years (6,103 days).

Biospecimens (3 samples)
- Sample 0DVM0K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVM1M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVM1Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
